Somatic mutation profile of tumor specimen 0DTHM7 from CCDI case PBCJND, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.6 years (2,425 days).
Specimen 0DTHM7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2459620d-2b90-4aff-9220-caab3eb19fc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTHMD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fc60cf7-5a21-44eb-8648-63c721321123

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Frame Shift Del 2, Intron 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KAT7 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 140/319 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs1000080818; called by muse, mutect2, varscan2
- SPTBN4 | c.4739C>T p.A1580V | Missense Mutation (SNP) | VAF 143/340 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.213); catalogued as rs1376279601; called by muse, mutect2, varscan2
- TRPS1 | c.1172C>G p.S391C (on ENST00000220888 / NM_001330599.2; = p.S404C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 212/518 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.174); catalogued as rs1275768183; called by muse, mutect2, varscan2
- TSC1 | c.1904_1905del p.T635Rfs*52 | Frame Shift Del (DEL) | VAF 144/269 reads (54%) | catalogued as rs118203597; called by pindel, varscan2
- ASB16 | c.163T>A p.S55T | Missense Mutation (SNP) | VAF 105/228 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH9 | c.174T>G p.N58K | Missense Mutation (SNP) | VAF 144/376 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, varscan2
- MARCKS | c.180_186del p.N61Afs*41 | Frame Shift Del (DEL) | VAF 83/547 reads (15%) | called by mutect2, pindel, varscan2
- PTCH1 | c.3453_3462delinsA p.Y1151_A1154delins* | Nonsense Mutation (DEL) | VAF 246/319 reads (77%) | called by pindel, varscan2*
- PKHD1 | c.4113G>A p.K1371= | Silent (SNP) | VAF 131/366 reads (36%) | catalogued as rs1029566251; called by muse, mutect2, varscan2
- DNAJC19 | c.280+39G>T | Intron (SNP) | VAF 80/206 reads (39%) | called by muse, mutect2, varscan2
